Gene-level copy-number profile of tumor specimen ALCH-B1LK-TTP1-A from ALCHEMIST case ALCH-B1LK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 64.8 years (23,651 days).
Specimen ALCH-B1LK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8cb9c6fb-0c72-439e-9bed-4ceca6a86c4b.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1LK-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,719 have no estimate.
https://portal.gdc.cancer.gov/files/593e6115-3814-4b1e-9201-fa92d3782d68

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 951; copy number 2: 19,511; copy number 3: 17,479; copy number 4: 13,275; copy number 5: 3,371; copy number 6: 1,438; copy number 7: 272; copy number 8: 2,318; copy number 9: 49; copy number 11: 103; copy number 12: 17; copy number 16: 2; copy number 19: 61.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:141,167,257–141,208,376, 2 genes (within-gene range 0–3): RNU6-904P, RPS16P3.
- chr2:219,482,073–219,516,877, 5 genes (within-gene range 0–2): ASIC4-AS1, AC053503.6, SPEGNB, AC053503.4, GMPPA.
- chr2:238,100,340–238,133,287, 1 gene: ESPNL.
- chr5:127,143,082–127,179,900, 4 genes: MRPS5P3, AC011416.1, SELENOTP2, AC011416.2.
- chr14:36,788,644–36,952,391, 3 genes (within-gene range 0–2): AL162464.2, AL162464.1, MIR4503.
- chr14:42,608,868–42,609,577, 1 gene (within-gene range 0–2): AL442163.2.
- chr14:102,539,644–102,539,726, 1 gene: MIR4309.
- chr14:105,140,982–105,168,824, 2 genes (within-gene range 0–2): JAG2, MIR6765.
- chr15:20,729,747–20,901,609, 14 genes: AC012414.4, RNU6-498P, AC012414.2, AC012414.3, LONRF2P3, AC012414.6, GRAMD4P5, AC012414.1, MIR3118-2, POTEB2, RNU6-749P, AC012414.5, AC037471.2, ZNF519P2.
- chr16:67,163,385–67,247,481, 12 genes (within-gene range 0–2): AC074143.1, HSF4, NOL3, KIAA0895L, EXOC3L1, E2F4, ELMO3, MIR328, AC040160.2, LRRC29, TMEM208, FHOD1.
- chr17:18,426,861–18,551,705, 11 genes (within-gene range 0–2): KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2, FAM106A, USP32P2, SRP68P2.
- chr18:79,470,120–79,470,940, 1 gene (within-gene range 0–2): AC018445.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,822 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:151,800,264–154,870,281, 164 genes, copy number 7 (broad region; genes not listed).
- chr1:163,769,339–248,937,043, 1,658 genes, copy number 8 (broad region; genes not listed).
- chr2:90,220,727–90,235,370, 2 genes, copy number 16: IGKV1D-8, IGKV3D-7.
- chr3:164,171,471–198,123,232, 623 genes, copy number 7–8 (broad region; genes not listed).
- chr5:92,151–17,620,939, 319 genes, copy number 7–19 (broad region; genes not listed).
- chr5:17,647,712–23,014,527, 41 genes, copy number 8: AC233724.1, AC233724.5, AC233724.2, H3Y1, AC233724.8, H3P22, LINC02223, RPL36AP21, SNORD81, RN7SL58P, LINC02100, UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP, AC106744.1, AC106744.2, RPL32P14, HSPD1P15, CDH18, AC093303.1, AC094103.1, CDH18-AS1, LINC02146, LINC02241, AC138938.1, AC140172.1, AC093274.1, GUSBP1, AC138951.1, AC138951.2, AC091946.2, AC091946.1, CDH12, HSPD1P1, AC139497.1, PMCHL1, AC138854.1, GCNT1P2, AC091938.1, AC010445.1.
- chr10:77,730,766–77,953,876, 10 genes, copy number 7: AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5.
- chr15:20,916,686–21,058,440, 5 genes, copy number 8 (within-gene range 2–8): NF1P1, MIR5701-1, LINC01193, OR11J2P, OR11J5P.

Autosomal genes at a single copy (total copy number 1): 947. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
